Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2MQ, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2MQ-06A (Metastatic).

[page 1 of 2]
Deliver To:

Patient Details:

DoB:

Sex: F

Ward:

Received

Lab No

SPECIMEN TYPE: Axilla

Biopsy No:

CLINICAL NOTES:

Recurrent melanoma Rt axilla. Rt posterior thorax.

The specimen was received fresh for tumour banking (largest node sampled).

MACROSCOPIC:

A) 'Wide local excision melanoma short superior, long lateral'. The specimen consists of an ellipse of skin 165 x 40mm to a depth of 25mm. There is short stitch indicating superior and designated 12 o'clock and a long stitch indicating lateral designated 9 o'clock. The 12 o'clock half inked blue, 6 o'clock black. There is a curvilinear scar 70mm in length and an area of puckering 25mm inferior to the scar. There is a bluish black raised nodule within the area of puckering 3 x 3mm. The scar and the nodule are well away from the lateral resection margin, 40 and 75mm away. Sectioning reveals a well circumscribed pinkish tan nodule with a blackened centre 18 x 13 x 10mm in the subcutis lying 15mm from the lateral resection margin and well away from the medial resection margin. It is 12mm from superior resection margin and 20mm from the inferior resection margin.

Blocks 1 to 5: Scar including superficial nodule in blocks 2 and 4

Blocks 6 and 7: Subcutaneous nodule with lateral resection margin

Blocks 8 to 10: Subcutaneous nodule under skin near lateral resection margin

B) 'Posterior lateral margin'. The specimen consists of fibrofatty tissue 45 x 22 x 10mm. Representative sections in two blocks.

C) 'Nodule from right latissimus dorsi muscle'. The specimen consists of fibrofatty tissue 53 x 20 x 15mm. The cut surface shows a tan nodule 6mm. Representative sections in four blocks.

D) 'Nodule right breast 10 o'clock'. The specimen consists of a nodule of yellowish tan tissue partly covered by skin 8 x 5 x 4mm. All embedded in one block.

E) 'Nodule right breast 12 o'clock'. The specimen consists of a piece of fibrofatty tissue partly covered by skin 5 x 5 x 4mm. All embedded in one block.

MICROSCOPIC:

A) The sections show skin and underlying subcutis. There are a total of six separate nodules of malignant melanoma. The tumour nodules are composed of large, epithelioid cells with ample cytoplasm and pleomorphic nuclei. Some cells contain melanin pigment. The largest deposit is 15mm in diameter and lies in the subcutaneous fat. Another three nodules of subcutaneous melanoma are present ranging from 0.5mm up to 10mm across. The largest of these appears to

100-0-3

Melanoma, NOS 8920/3

Site: lymph node, axilla

C77-3

AW

8/24/11

HISTOPATHOLOGY

ANATOMICAL PATHOLOGY

[page 2 of 2]
Requesting Doctor's Information: Deliver To:	Patient Details: DoB: _____ Sex: F Ward: _____
--	---

Received

SPECIMEN TYPE: Axilla

Biopsy No:

replace a lymph node, and is present at the deep margin of excision (In the 9 o'clock part of the specimen, adjacent to the lateral stitch). Two dermal nodules of melanoma are present near an area of scarring. There is no epidermal abnormality. The tumour cells stain positively with S100 and show patchy positivity with HMB45. They are negative for MelanA and pan-cytokeratin.

B) The sections show subcutaneous adipose tissue with no evidence of malignancy.

C) The sections show skeletal muscle, nerves and fat with a single lymph node. The lymph node shows partial replacement by a 5mm deposit of metastatic melanoma (1/1). The melanoma appears excised by 0.2mm. There is no direct involvement of the skeletal muscle.

D) The section shows skin with subcutis. The skin is vaguely polypoid. This may represent a fibroepithelial polyp (skin tag). There is no evidence of malignancy.

E) The section shows skin with subcutis with a polypoid area suggestive of a fibroepithelial polyp (skin tag). There is no evidence of malignancy.

SUMMARY:

A) Skin right axilla: Dermal and subcutaneous recurrent melanoma. One lymph node involved. Focal involvement of deep lateral margin.

B) Posterior lateral margin: No evidence of malignancy.

C) Nodule from right latissimus dorsi muscle: Metastatic melanoma in one lymph node.

D) Nodule right breast 10 o'clock: Favour fibroepithelial polyp.

E) Nodule right breast 12 o'clock: Favour fibroepithelial polyp.

REPORTING PATHOLOGIST:

(Electronic Signature)

HISTOPATHOLOGY

ANATOMICAL PATHOLOGY

Where 'Collected'	Page 2 of 2
-------------------	-------------

Management:

Where 'Collected'

Source: NCI Genomic Data Commons file 22dc46b4-d6e7-4b97-af5e-53e7325a7dbb (TCGA-EE-A2MQ.FAE58E93-F785-4604-9D6B-395AA55C054D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).